Somatic mutation profile of tumor specimen TCGA-B9-7268-01A (aliquot TCGA-B9-7268-01A-11D-2136-08) from TCGA case TCGA-B9-7268, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 59.4 years (21,705 days).
Specimen TCGA-B9-7268-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8264c99f-c0f6-4123-aab6-0fb0ab047358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-7268-10A (Blood Derived Normal), aliquot TCGA-B9-7268-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9afdf2b9-fee2-4f35-b53d-20ab23b00861

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 29, Silent 17, Frame Shift Del 4, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANP32D | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV56980992; called by muse, mutect2, varscan2
- APOLD1 | c.436C>T p.R146W (on ENST00000326765 / NM_001130415.2; = p.R115W on NM_030817.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs768382313, COSV100458911; called by mutect2, varscan2
- ATP1A3 | c.239C>T p.P80L (on ENST00000545399 / NM_001256214.2; = p.P67L on NM_152296.5) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV57491408; called by muse, mutect2, varscan2
- BEST4 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64734545; called by muse, mutect2
- COPS9 | c.115G>C p.V39L (on ENST00000607357 / NM_001163424.2; = p.V70L on NM_138336.1) | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV56228451, COSV56229009, COSV56229090; called by muse, mutect2, varscan2
- CUTC | c.486A>C p.L162F | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV65082258; called by muse, mutect2, varscan2
- DNAH8 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59482308; called by muse, mutect2, varscan2
- FAM187B | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV61201796; called by muse, mutect2, varscan2
- FAT1 | c.7138G>A p.V2380I | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs201352448, COSV101499663; called by muse, mutect2
- FUCA1 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65694701; called by muse, mutect2, varscan2
- GATC | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV56664269; called by muse, mutect2, varscan2
- GGCX | c.2077C>A p.R693S | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52090533; called by muse, mutect2, varscan2
- GINS2 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53681285; called by muse, mutect2, varscan2
- GSDME | c.1169T>A p.V390D | Missense Mutation (SNP) | VAF 89/151 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61652992; called by muse, mutect2, varscan2
- KIAA1109 | c.11522A>G p.K3841R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs774954246, COSV52693854; called by muse, mutect2, varscan2
- KRT4 | c.578G>C p.S193T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53407753, COSV53409917; called by muse, mutect2, varscan2
- MACF1 | c.5436G>C p.Q1812H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV57145361; called by muse, mutect2, varscan2
- MCAM | c.999T>G p.S333R | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV50665572; called by muse, mutect2, varscan2
- NEB | c.6982G>A p.D2328N | Missense Mutation (SNP) | VAF 135/268 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51461826; called by muse, mutect2, varscan2
- NISCH | c.4324C>A p.L1442I | Missense Mutation (SNP) | VAF 127/410 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV58743430; called by muse, mutect2, varscan2
- NUDT6 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV56784927; called by muse, mutect2, varscan2
- RAPGEF4 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs750231631, COSV51417388; called by muse, mutect2, varscan2
- SCARF2 | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1263267535, COSV56734107; called by muse, mutect2, varscan2
- STXBP3 | c.356T>G p.F119C | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64183642; called by muse, mutect2, varscan2
- TERF2 | c.881G>C p.S294T | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV54749174; called by muse, mutect2, varscan2
- TTLL3 | c.2656G>A p.V886M | Missense Mutation (SNP) | VAF 101/289 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV59615925; called by muse, mutect2, varscan2
- UBE4A | c.760G>A p.E254K (on ENST00000252108 / NM_001204077.2; = p.E261K on NM_004788.4) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV52807087; called by muse, mutect2, varscan2
- ZNF780B | c.1972C>G p.Q658E | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV55468523; called by muse, varscan2
- BCLAF1 | c.2610del p.Q870Hfs*77 | Frame Shift Del (DEL) | VAF 84/221 reads (38%) | called by mutect2, pindel, varscan2
- C1orf54 | c.189+5_189+8del p.X63_splice | Splice Site (DEL) | VAF 15/67 reads (22%) | called by pindel, varscan2
- CSPP1 | c.2424del p.A810Qfs*27 (on ENST00000676605; = p.A769Qfs*27 on NM_024790.6) | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- LIPA | c.1039del p.A348Qfs*10 | Frame Shift Del (DEL) | VAF 55/157 reads (35%) | called by mutect2, pindel, varscan2
- LTBP1 | c.1280del p.G427Efs*40 (on ENST00000404816 / NM_206943.4; = p.G101Efs*40 on NM_000627.4) | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2
- LTBP1 | c.1285C>A p.L429I (on ENST00000404816 / NM_206943.4; = p.L103I on NM_000627.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, varscan2
- REPIN1 | c.534dup p.C179Mfs*24 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF28 | c.1269T>C p.S423= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV55271138; called by muse, mutect2, varscan2
- CBR4 | c.33C>A p.S11= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV60370942; called by muse, mutect2, varscan2
- COX10 | c.573T>A p.L191= | Silent (SNP) | VAF 184/287 reads (64%) | catalogued as COSV55409162; called by muse, mutect2, varscan2
- LRRIQ1 | c.1281G>T p.V427= | Silent (SNP) | VAF 31/251 reads (12%) | catalogued as COSV67839160; called by muse, mutect2, varscan2
- MCMBP | c.1377T>C p.D459= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV63510767; called by muse, mutect2, varscan2
- MNAT1 | c.822T>C p.H274= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs751662718, COSV54196593; called by muse, mutect2, varscan2
- NIPAL2 | c.852T>A p.I284= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV57843630; called by muse, mutect2, varscan2
- PABPC4 | c.1470G>A p.L490= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV63293722; called by muse, mutect2, varscan2
- PRAG1 | c.816T>A p.T272= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV58167216; called by muse, mutect2, varscan2
- SMARCA4 | c.3801C>A p.G1267= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV60810036; called by muse, varscan2
- SPRR1B | c.144C>T p.P48= | Silent (SNP) | VAF 96/250 reads (38%) | catalogued as rs766791483, COSV61068114; called by muse, mutect2
- SYCP3 | c.489A>G p.Q163= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV57150206; called by muse, mutect2, varscan2
- TMEM268 | c.694T>C p.L232= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as rs774968958, COSV55987709; called by muse, mutect2, varscan2
- TNS1 | c.1881C>G p.P627= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV50773461; called by muse, mutect2, varscan2
- USF3 | c.3849C>A p.G1283= | Silent (SNP) | VAF 125/199 reads (63%) | catalogued as COSV57077689; called by muse, mutect2, varscan2
- ZNF687 | c.606C>G p.A202= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV60682469; called by muse, mutect2, varscan2
- ZNF836 | c.840C>T p.G280= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs1311318338, COSV59087005; called by muse, mutect2, varscan2
